Surgical pathology report (de-identified scan), TCGA case TCGA-24-1103, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1103-01A (Primary Tumor).

[page 1 of 6]
Patient Name:

DOB:

Surgical Pathology Report

Final

SURGICAL PATHOLOGY REPORT

Patient Name:
Address:

Service:
Location:
MRN:
Hospital #
Patient Type

Accession #:
Taken:
Received:
Reported:

Gender:
DOB:

Physician(s):

Other Related Clinical Data:

DIAGNOSIS:

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA WITH FOCAL ENDOMETRIOID DIFFERENTIATION
(SEE SYNOPSIS)

- THE TUMOR INVOLVES THE OVARIAN SURFACE AND AND PARAOVARIAN SOFT TISSUE
- LYMPHATIC-VASCULAR SPACE INVASION IS IDENTIFIED

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA WITH FOCAL ENDOMETRIOID DIFFERENTIATION
(SEE SYNOPSIS)

- THE TUMOR INVOLVES THE OVARIAN SURFACE AND AND PARAOVARIAN SOFT TISSUE
- LYMPHATIC-VASCULAR SPACE INVASION IS IDENTIFIED

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY, INVOLVING PARATUBAL SOFT
TISSUE, BUT NOT TUBAL WALL

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY

- INTRALUMINAL GRANULATION TISSUE WITH PSAMMOMA BODIES
- NO EVIDENCE OF CARCINOMA

UTERUS AND CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- CHRONIC CERVICITIS
- INACTIVE ENDOMETRIUM
- LEIOMYOMAS
- SEROSAL ADHESIONS WITH GRANULATION TISSUE
- METASTATIC ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY, INVOLVING FOCALLY SEROSA

FALCIFORM LIGAMENT AND LIVER, BIOPSIES

- METASTATIC ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY, INVOLVING SOFT TISSUE AND

HEPATIC CAPSULE

NO INVOLVEMENT OF HEPATIC PARENCHYMA IDENTIFIED

[page 2 of 6]
Patient Name:

DOB:

OMENTUM, EXCISION

- METASTATIC ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY

TUMOR, RIGHT HEMIDIAPHRAGM, BIOPSIES

- METASTATIC ADENOCARCINOMA CONSISTENT WITH OVARIAN PRIMARY

BREAST, RIGHT, EXCISIONAL BIOPSY

- INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, GRADE III/III (SEE COMMENT AND SYNOPTIC)
- TUMOR SIZE = 1.5 CM
- NO IN-SITU COMPONENT IS PRESENT
- NO LYMPHATIC-VASCULAR SPACE INVASION IS IDENTIFIED
- TUMOR APPROACHES TO WITHIN 0.3 CM OF LATERAL RESECTION MARGIN

SENTINEL LYMPH NODE, BREAST, RIGHT, EXCISION

- NO EVIDENCE OF CARCINOMA IN ONE LYMPH NODE (0/1)

NON-SENTINEL LYMPH NODE, BREAST, EXCISION

- NO EVIDENCE OF CARCINOMA IN ONE LYMPH NODE (0/1)

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Called to pickup 'right breast' consisting of an oriented 45-gram portion of fatty breast tissue measuring 6 cm superior to inferior, 5 cm medial to lateral and 2 cm anterior to posterior. The specimen is inked as follows: anterior, black; posterior, blue; superior and inferior, yellow; medial and lateral, green. The specimen is divided into medial and lateral halves and serially sectioned. All for permanents," by .

FS: Right ovarian biopsy

- "Mullerian neoplasm of at least borderline malignant potential," by

Microscopic Description and Comment:

The immunohistochemical stains were performed and the results are as follows:

Tissue origin	Ovary (B12)	Omentum (C1)	Breast (H1)
Cytokeratin 7	diffuse positive	diffuse positive	diffuse positive
Cytokeratin 20	negative	negative	negative
Estrogen receptor	focal positive	focal positive	negative
Progesterone receptor	focal positive	focal positive	negative
CEA	focal positive	negative	negative
CA125	diffuse positive	diffuse positive	focal positive
GCDFP-15	negative	negative	negative
WT1	diffuse positive	diffuse positive	negative
B72.3	focal positive	focal positive	negative

[page 3 of 6]
Patient Name:

DOB:

In view of this immunohistochemical profile, the breast adenocarcinoma represents a separate, synchronous primary rather than a metastasis from ovarian primary. The omental tumor represents a metastasis from the ovarian primary.

has reviewed the immunohistochemical results and selected HE slides and concurs with above interpretation. (

History:

The patient is a year old woman with history of breast carcinoma and metastatic peritoneal disease. Operative procedure: Evaluation under anesthesia, total abdominal hysterectomy/bilateral salpingo-oophorectomy, omentectomy, right breast biopsy with sentinel lymph node biopsy.

Specimen(s) Received:

- A: RIGHT OVARIAN BIOPSY
- B: UTERUS/CERVIX/BSO
- C: TUMOR FROM FALCIFORM AND LIVER
- D: OMENTUM
- E: RIGHT HEMI-DIAPHAM TUMOR
- F: SENTINEL LYMPH NODE-BREAST, RIGHT
- G: NON-SENTINEL LYMPH NODE-BREAST
- H: RIGHT BREAST SHORT SUPERIOR LONG LATERAL

Gross Description

The specimens are received in eight formalin-filled containers, each labeled with the patient's name. The first container is labeled "right ovarian biopsy, FS/X." It contains a white cassette which contains a 1 cm, circular fragment of firm tan tissue, submitted labeled A1. Also present, in the container, are two irregular fragments of soft light tan tissue, measuring 1.5 and 0.7 cm. Submitted, labeled A2. Jar 0.

The second container is labeled "uterus/cervix/bilateral salpingo-oophorectomy." It contains a uterus with attached fallopian tubes and bilateral adnexal masses. The uterus measures 7 cm superior to inferior, 5 cm cornu to cornu and 4.5 cm anterior to posterior. The cervix measures 3 x 2.5 x 3 cm. There is no vaginal cuff. The ectocervix, measuring 3 x 3 x 0.8 cm appears grossly unremarkable. The cervical os is slit-like, measuring 0.7 cm. The uterus is distorted by a intramural nodule measuring 3.5 x 2.5 cm, arising in the myometrium of fundus. The endometrial cavity is somewhat compressed, measuring 3 x 2.5 cm. A separate nodule with a firm, whorled cut surface, is noted in the posterior myometrium, measuring 0.8 cm in the greatest dimension. The cervical canal measures 3 cm in length and shows a tan, herring bone mucosa with attached mucus. Sectioning through the larger myoma shows a grey-white, firm, whorled appearance without necrosis or hemorrhage. The right adnexal structures are congested and edematous, and grossly distorted by a mass, measuring 7.5 x 5 x 6 cm. It has a multicystic outer appearance with areas of firmness as well as small papillary areas growing from the surface. The fallopian tube is separate from this mass, somewhat irregular in appearance, measuring 5 cm in length. Areas of firmness are noted in the immediate vicinity of the fallopian tube, within the proximal one-third, measuring 1.5 cm and 1 cm. No normal ovarian tissue is grossly identified. Cut surface of the adnexal mass shows a multiloculated, cystic appearance with cysts varying in size from 3.5 cm to 2 cm. Some of the cysts are filled with dirty, gelatinous, yellow material, while others show gelatinous, hemorrhagic material. Solid, irregular areas are identified in the walls of all the cysts. The left adnexal mass measures 8 x 6 x 3.5 cm. The fallopian tube is congested and edematous in appearance and measures 6 cm in length. The cut surface of this adnexal mass shows a partially cystic appearance with multiple solid, papillary areas, and nodules, the largest nodule measuring

[page 4 of 6]
Patient Name: _____

4 cm. The cyst measures 3.5 cm in greatest circumference. The fallopian tube grossly is not involved by the tumor.

Submitted: labeled B1-B2 - anterior cervix; B3-B4 - posterior cervix; B5 - anterior endomyometrium; B6 - posterior endomyometrium; B7 - large myoma; B8 - small myoma; B9-B12 - right adnexal mass; B13 - right fallopian tube; B14 - left adnexal mass, surface; B15-B17 - random left adnexal mass; B18 - left fallopian tube. Jar 2.

The third container is labeled "omentum." It contains a stretch of omentum measuring 50 cm in length and 18 x 3.5 cm in other dimensions. It shows extensive caking due to tumor involvement around the edges, the largest area measuring 15.5 x 5 x 2 cm. Random representative sections submitted, labeled C1-C4. Jar 3.

The fourth container is labeled "tumor from falciform ligament, liver." It contains an irregular fragment of congested, friable tissue with attached adipose tissue, measuring 5.5 x 3.5 x 1 cm in entire dimensions. Cut surface has a firm grey-white appearance alternating with normal-appearing adipose tissue. Random representative sections submitted, labeled D1 and D2. Jar 1.

The fifth container is labeled "right hemidiaphragm tumor." It contains a flat tissue fragment, measuring 8.5 x 6 x 1 cm. It has an irregular, papillary appearance with firm, grey-white cut surface. Random representative sections submitted, labeled E1 and E2. Jar 1.

The sixth container is labeled "sentinel node (biopsy right breast)." It contains a nodule, measuring 2.4 x 1.2 x 0.8 cm with attached adipose tissue. Cut surface is green-tan in appearance. Submitted, labeled F1. Jar 0.

The seventh container is labeled "non-sentinel node biopsy right breast." It contains a firm nodule, measuring 1.5 x 0.9 x 0.5 cm, with attached adipose tissue. Submitted, labeled G1. Jar 0.

The eighth container is labeled "right breast - short superior, long lateral." The specimen is received in formalin with attached long suture. The short suture is not present. The specimen has been previously handled for intraoperative consultation. The dimensions and inked margins are noted in consistence with the intraoperative, non-microscopic consultation. No skin is present. An irregular, firm, gray-white area, measuring approximately 1.5 cm is noted, closely abutting the green (lateral) margin. Serial sectioning of the remaining tissue shows predominantly adipose tissue with soft fibrous areas. Submitted, labeled H1-H5 - entire firm area in relation to margins; H6-H9 - random breast. Jar 1.

Synopsis

FIRST SYNOPTIC:

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma with focal endometrioid differentiation
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of >50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)

[page 5 of 6]
Patient Name:

OB: .

6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES NOT invade the adjacent fallopian tube.
9. Tumor invasion of pelvic soft tissue CANNOT BE EVALUATED.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC PERITONEUM is PRESENT.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is: 15.5 cm .
14. Metastatic involvement of the uterine serosa is FOCALLY PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is: 0
18. Extranodal extension by tumor is NOT APPLICABLE.
19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is
classified as:

TNM Scheme	FIGO Scheme	Definition
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring > 2cm in greatest dimension.

THE REGIONAL LYMPH NODES are classified as:

NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/UICC/FIGO STAGE IS:

AJCC/UICC/FIGO

least IIIC (T3c/N0/M0)

SECOND SYNOPTIC:

SYNOPTIC WORKSHEET - PARTIAL/TOTAL MASTECTOMY FOR BREAST CANCER

1. A NEOPLASM is present.
2. THE LOCATION OF THE TUMOR IS: (Check all that apply)
Not specified
THE LOCATION OF THE PREVIOUS TUMOR IS:
Right breast, not otherwise specified
3. THE TUMOR IS GROSSLY:
Unifocal
4. The SAMPLED MARGINS OF EXCISION are:
Uninvolved by tumor.
5. THE POSITIVE MARGIN(S) OF EXCISION is/are:
Not applicable; no margins are positive.
6. AN INVASIVE TUMOR COMPONENT is:
Present.
7. THE HISTOLOGIC CLASSIFICATION of the invasive tumor is:
Ductal adenocarcinoma, conventional type.
8. THE MAXIMUM DIAMETER OF THE INVASIVE TUMOR is: 1.5 cm.
9. THE BORDERS OF THE INVASIVE TUMOR are:
"Pushing"
10. LYMPHOID RESPONSE TO THE INVASIVE TUMOR is:
Slight.
11. NECROSIS WITHIN THE INVASIVE TUMOR is:
Moderate.
12. LYMPHATIC INVOLVEMENT BY INVASIVE TUMOR is:
Absent.
13. DERMAL INVOLVEMENT BY INVASIVE TUMOR is:
Not evaluable.

[page 6 of 6]
Patient Name:

DOB:

14. MAMMARY PAGET'S DISEASE is:

Not evaluable.

15. THE PAGE & ANDERSON GRADE OF THE INVASIVE TUMOR is:

III/III.

16. THE BRODERS' GRADE OF THE INVASIVE TUMOR is:

G3 (Poorly-differentiated)

17. IN-SITU CARCINOMA is:

Absent.

18. THE HISTOLOGIC TYPE OF THE IN-SITU CARCINOMA COMPONENT is:

Not applicable; no in-situ component is present.

19. NUCLEAR GRADE OF THE IN-SITU CARCINOMA COMPONENT is:

Not applicable.

20. IN-SITU CARCINOMA IS PRESENT in:

0% of the specimen.

21. MICROCALCIFICATIONS are:

Absent.

22. THE NON-NEOPLASTIC BREAST TISSUE SHOWS:

No histologic abnormalities

23. STAGING INFORMATION

(USE THE FOLLOWING "(A)" STATEMENT FOR MASTECTOMY SPECIMENS WHERE THERE IS NO RESIDUAL CARCINOMA AFTER A PREVIOUS BIOPSY)

(B) Data provided in this section DO NOT include information from a prior biopsy from the same patient (i.e., no prior excisional biopsy has been obtained for microscopic examination) "T" DATA: The tumor is:

T1c (Tumor > 1 cm but < or = 2 cm in maximum dimension)

"pN" DATA: The regional lymph nodes are classified as:

pN0 (Devoid of metastases)

THE TOTAL NUMBER OF LYMPH NODES EXAMINED is: 2.

THE TOTAL NUMBER OF POSITIVE NODES is: 0.

Extranodal extension by metastatic tumor is:

Not applicable; no metastases are present

"M" DATA: The tumor is classified as:

MX (The presence of distant metastases cannot be evaluated)

24. THE OVERALL PATHOLOGIC AJCC STAGE OF THE TUMOR is:

Stage I (T1/ pN0/ M0)

25. TUMOR TISSUE TO BE USED FOR MEASUREMENT OF ESTROGEN AND PROGESTERONE RECEPTOR PROTEINS was:

Estrogen and progesterone receptors are negative by immunohistochemical analysis.

Source: NCI Genomic Data Commons file 3c06a252-cff9-4e95-8074-b26167439877 (TCGA-24-1103.B9628222-5530-4A82-9F13-2773173A0C95.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).